Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5159, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5159-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

Kidney, right, laparoscopic radical nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, clear cell type

Histologic grade (if applicable): 3 (of 4, Fuhrman classification)

Tumor size (greatest dimension): Multifocal (3 nodules), largest 1.9 cm in diameter

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Not identified

Gerota's fascia: Not received

Renal vein: Not involved

Ureter: Not involved

Venous (large vessel) Not involved

Lymphatic (small vessel): Not involved

Adjacent organs: Not sampled

Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Adrenal gland: Not received

Lymph nodes: None received

Other significant findings:

- Chronic interstitial nephritis
- Arteriolonephrosclerosis

AJCC Staging: pT1a pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with right renal mass.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Radical laparoscopic

Side of specimen: Right

Size and weight of specimen: 500 grams; 22 x 12 x 5 cm (overall nephrectomy specimen), 11 x 5.8 x 4.7 cm (kidney)

Orientation: Perinephric fat inked blue, ureter/yellow for orientation.

[page 2 of 2]
Presence/absence of adrenal gland: Absent

Tumor description/site: The tumor is multifocal with the largest mass (mass #1 -1.5 x 1.4 x 1.9 cm) located in the medulla of the inferior pole. Mass #1 is fairly well circumscribed with a firm, partially cystic orange/yellow cut surface. Focal hemorrhage is noted. The mass abuts and expands the renal pelvis, but no gross invasion into the hilum is observed. The mass measures 3.4 cm from the renal capsule and 1.4 cm from the nearest blue inked perinephric soft tissue margin.

A second similar orange-yellow satellite lesion (mass #2 -0.6 cm diameter) is noted 0.4 cm inferior to the first described mass. A third well-circumscribed tan/brown hemorrhagic lesion (mass #3 - 0.5 cm diameter) is noted in the cortex of the mid-upper pole and is noted slightly expanding the capsule of the kidney. This lesion measures 0.4 cm from the closest blue inked perinephric soft tissue.

Confinement/non-confinement to the kidney: All lesions are grossly confined to the kidney.

Extent of invasion:

Perirenal adipose tissue: Does not involve

Gerota's fascia: Does not involve

Renal vein: Does not involve

Ureter: Does not involve

Other organs: Does not involve

Surgical margins:

Perirenal adipose tissue: Negative, by 0.4 cm in mass #3

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: Pink/tan and unremarkable with preserved cortical structure.

Lymph nodes (hilar): Submitted per block summary.

Other significant findings: None

Tissue submitted for special investigations: Tumor was collected by tissue procurement.

Digital photograph taken: No

Block Summary:

A1 - Ureter and vascular margins

A2 - Mass #3 with adjacent nearest blue inked perinephric soft tissue

A3 - Mass #1/2 with nearest blue inked perinephric soft tissue margin

A4 - Mass #1 with full thickness section of underlying hilum

A5 - Mass #1 adjacent to renal vasculature

A6 - Mass #1 expanding the renal pelvis

A7 - Normal kidney

A8-A9 - Hilar tissue

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed

Signature

Resident Physician:

[Redacted Signature]

Source: NCI Genomic Data Commons file 97a8fc36-c9c8-41be-8291-d1d381557e75 (TCGA-B8-5159.FA093376-3F7C-4EBB-8996-6B683C3482C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).